Somatic mutation profile of tumor specimen TCGA-CV-7177-01A (aliquot TCGA-CV-7177-01A-11D-2012-08) from TCGA case TCGA-CV-7177, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 82.6 years (30,180 days).
Specimen TCGA-CV-7177-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70d866e1-ee1f-4104-b34b-af90f90f9479.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7177-10A (Blood Derived Normal), aliquot TCGA-CV-7177-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e94e33e-d4b3-4eee-9f43-c602d7216ea8

The open-access MAF lists 107 somatic variants for this specimen: 77 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 29, Nonsense Mutation 5, Splice Site 4, Frame Shift Del 3, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSD17B3 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs28939085, CM940952; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 43/70 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AADACL4 | c.1003C>G p.Q335E | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100879429; called by muse, mutect2
- ADAM29 | c.433T>A p.F145I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100822042; called by muse, mutect2, varscan2
- ADCY1 | c.2182C>T p.H728Y | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV52046013; called by muse, mutect2, varscan2
- AJUBA | c.913del p.E305Sfs*105 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as COSV99401004; called by mutect2, pindel, varscan2
- AKAP14 | c.525G>T p.W175C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV100538310; called by muse, mutect2, varscan2
- ANGPTL4 | c.758-1G>A p.X253_splice | Splice Site (SNP) | VAF 17/59 reads (29%) | catalogued as COSV100035166; called by muse, mutect2, varscan2
- APBA1 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 68/233 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99595955, COSV99596337; called by muse, mutect2, varscan2
- ARSJ | c.1463C>G p.S488* | Nonsense Mutation (SNP) | VAF 33/95 reads (35%) | catalogued as COSV100192785; called by muse, mutect2, varscan2
- ASXL1 | c.3016G>T p.E1006* | Nonsense Mutation (SNP) | VAF 33/85 reads (39%) | catalogued as COSV100039653, COSV60119945; called by muse, mutect2, varscan2
- ATP2B4 | c.1773G>C p.K591N | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100397604; called by muse, mutect2
- ATRN | c.3406G>A p.E1136K | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV99497305; called by muse, mutect2, varscan2
- BBX | c.2182G>T p.E728* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | catalogued as COSV100361712; called by muse, mutect2
- BEST3 | c.1838C>G p.S613C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.237); catalogued as COSV100437804; called by muse, mutect2, varscan2
- BRF2 | c.1260A>G p.*420Wext*20 | Nonstop Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV99604982; called by muse, mutect2, varscan2
- BTBD11 | c.1898A>G p.E633G (on ENST00000280758 / NM_001018072.2; = p.E170G on NM_001017523.2) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99776052; called by muse, mutect2, varscan2
- CASKIN2 | c.2434G>A p.E812K | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100050539; called by muse, mutect2, varscan2
- CBX2 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 20/33 reads (61%) | catalogued as COSV99490907; called by muse, mutect2, varscan2
- CCDC88A | c.4716T>A p.D1572E (on ENST00000436346 / NM_001365480.1; = p.D1544E on NM_018084.5) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.86); PolyPhen benign (0.09); catalogued as COSV99710585; called by muse, mutect2, varscan2
- CNTNAP4 | c.3200C>G p.S1067C | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271815, COSV56671209; called by muse, mutect2, varscan2
- COMTD1 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV100040990; called by muse, mutect2, varscan2
- CUL4B | c.2434G>C p.D812H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.709); catalogued as COSV100340678; called by muse, mutect2, varscan2
- DDC | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100779463; called by muse, mutect2
- DENND2D | c.1100C>G p.T367S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as COSV100718691; called by muse, mutect2, varscan2
- DSG4 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100355978; called by muse, mutect2, varscan2
- FAM184A | c.1332+1G>A p.X444_splice | Splice Site (SNP) | VAF 7/73 reads (10%) | catalogued as COSV58852491; called by muse, mutect2, varscan2
- GRIA3 | c.558G>T p.W186C | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99990529; called by muse, mutect2, varscan2
- GRM7 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0.188); catalogued as COSV100736929; called by muse, mutect2, varscan2
- IQGAP3 | c.841C>G p.Q281E | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs745968098, COSV100752177, COSV63250719; called by muse, mutect2, varscan2
- JAG2 | c.3541G>A p.E1181K | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.986); catalogued as rs367844673; called by muse, varscan2
- JARID2 | c.2407G>A p.D803N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.327); catalogued as COSV100521940; called by muse, mutect2, varscan2
- JPH4 | c.1549G>C p.E517Q | Missense Mutation (SNP) | VAF 19/213 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV100436798; called by muse, mutect2
- KDM6A | c.3655T>A p.W1219R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100938274; called by muse, mutect2, varscan2
- KHDRBS3 | c.269A>T p.E90V | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV100878761; called by muse, mutect2
- LAMA2 | c.5740G>T p.A1914S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs765600723, COSV101370527; called by mutect2, varscan2
- LCN1 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs772285152, COSV99704437; called by mutect2, varscan2
- LINGO4 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.853); catalogued as rs201618190; called by muse, mutect2, varscan2
- LRRC4C | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs1231833478, COSV53442104, COSV99538556; called by muse, mutect2, varscan2
- MAP3K4 | c.1188G>C p.W396C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100815446; called by muse, mutect2, varscan2
- MIOS | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV100402808; called by muse, mutect2, varscan2
- MMP2 | c.1969T>C p.W657R | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99527905; called by muse, mutect2
- MUC6 | c.2638G>C p.D880H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101424636; called by muse, mutect2, varscan2
- MYH7B | c.5884G>A p.E1962K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99328489; called by muse, mutect2, varscan2
- NLGN1 | c.1282G>C p.G428R | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.253); catalogued as COSV100849427; called by muse, mutect2
- NOB1 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199699618, COSV52062785, COSV52063026; called by mutect2, varscan2
- OSBPL2 | c.172C>G p.Q58E (on ENST00000313733 / NM_144498.4; = p.Q46E on NM_014835.4) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100569286, COSV100569384; called by muse, mutect2, varscan2
- PEF1 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.968); catalogued as rs759567297, COSV65483721; called by muse, mutect2, varscan2
- PLXND1 | c.4650C>A p.N1550K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100139904; called by muse, mutect2, varscan2
- PRAMEF12 | c.920C>G p.S307W | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100743325; called by muse, mutect2, varscan2
- PSAP | c.307T>G p.S103A | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.07); catalogued as COSV101206496; called by muse, mutect2, varscan2
- RALGAPB | c.4283G>A p.R1428Q | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99485351; called by muse, mutect2
- RNF213 | c.13013G>A p.R4338H | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60407456; called by muse, mutect2, varscan2
- SBF1 | c.3700G>T p.A1234S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0.028); catalogued as COSV100817812; called by muse, mutect2, varscan2
- SERPINA9 | c.950A>G p.N317S | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs769429068, COSV54077549; called by muse, mutect2
- SLC17A9 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.195); catalogued as rs772568745, COSV100947864; called by muse, mutect2, varscan2
- SLC22A12 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs542473712, COSV100327755, COSV60574554; called by muse, mutect2, varscan2
- SLC39A8 | c.626T>A p.L209H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV100765770; called by muse, mutect2, varscan2
- STAC3 | c.531_532del p.F178* | Frame Shift Del (DEL) | VAF 43/194 reads (22%) | catalogued as rs1430468647; called by pindel, varscan2
- TMC8 | c.1766G>C p.R589P | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.296); catalogued as COSV100573754; called by muse, mutect2
- TMEM145 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.802); catalogued as COSV100003913, COSV56625201; called by muse, mutect2, varscan2
- TNC | c.4960A>C p.I1654L | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.277); catalogued as COSV100405896; called by muse, mutect2, varscan2
- TRPM1 | c.4238A>G p.Y1413C | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs761450924, COSV99856077; called by muse, mutect2, varscan2
- TSSK2 | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV99350953; called by muse, mutect2, varscan2
- TTC23L | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV72205929; called by muse, mutect2
- TTC25 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as rs782259846, COSV101102991; called by muse, mutect2, varscan2
- TUBGCP6 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV99955721; called by muse, mutect2
- USP19 | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as rs372954314; called by muse, mutect2, varscan2
- VPS33B | c.1424T>G p.F475C | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100325621; called by muse, mutect2, varscan2
- WDR4 | c.36G>C p.Q12H | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100375269; called by muse, mutect2, varscan2
- ZBED9 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.443); catalogued as COSV101509273; called by muse, mutect2, varscan2
- ZNF208 | c.3055C>A p.H1019N | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101237052; called by muse, mutect2, varscan2
- ZNF626 | c.1201G>T p.E401* | Nonsense Mutation (SNP) | VAF 22/96 reads (23%) | catalogued as COSV101656991, COSV74129220; called by muse, varscan2
- TAPBP | c.1211-31_1216del p.X404_splice | Splice Site (DEL) | VAF 24/84 reads (29%) | called by mutect2, pindel
- TPD52L1 | c.133_135+8del p.X45_splice | Splice Site (DEL) | VAF 12/86 reads (14%) | called by mutect2, pindel
- YAF2 | c.349_356del p.E117Cfs*12 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- AADAC | c.735C>G p.L245= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV99233269, COSV99233286; called by muse, mutect2, varscan2
- ALG13 | c.2559T>C p.A853= | Silent (SNP) | VAF 24/212 reads (11%) | catalogued as COSV99322427; called by muse, mutect2, varscan2
- ATRN | c.3849C>T p.F1283= | Silent (SNP) | VAF 36/254 reads (14%) | catalogued as rs746813384, COSV99497307; called by muse, mutect2, varscan2
- CCL23 | c.309C>A p.L103= | Silent (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- DCX | c.633C>G p.L211= | Silent (SNP) | VAF 64/171 reads (37%) | catalogued as COSV57573985; called by muse, mutect2, varscan2
- EID2 | c.96G>A p.R32= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs1297927058, COSV101180487; called by muse, mutect2
- EPAS1 | c.1392C>T p.A464= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV99763289; called by muse, mutect2
- GPRASP2 | c.1470C>T p.T490= | Silent (SNP) | VAF 33/164 reads (20%) | catalogued as COSV100176780; called by muse, mutect2, varscan2
- H3C2 | c.102C>A p.G34= | Silent (SNP) | VAF 16/161 reads (10%) | catalogued as COSV99451520; called by muse, mutect2, varscan2
- IRS4 | c.996T>C p.C332= | Silent (SNP) | VAF 107/317 reads (34%) | catalogued as COSV100929594; called by muse, mutect2, varscan2
- JPH3 | c.2091C>T p.F697= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs1019906565, COSV52466384; called by muse, mutect2, varscan2
- KIF5A | c.2781C>T p.Y927= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as rs767928175, COSV99673114; called by muse, mutect2, varscan2
- LRRTM3 | c.507G>A p.L169= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as COSV63669929; called by muse, mutect2, varscan2
- MBOAT7 | c.1044C>T p.T348= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs1236866298, COSV99824872; called by mutect2, varscan2
- NSMCE1 | c.657C>T p.Y219= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs371500174; called by muse, mutect2, varscan2
- OR2A2 | c.75C>G p.L25= | Silent (SNP) | VAF 9/187 reads (5%) | catalogued as COSV101286651; called by muse, mutect2
- PAQR8 | c.765C>T p.F255= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV62442638; called by muse, mutect2, varscan2
- PDAP1 | c.42G>T p.A14= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV99769121; called by muse, mutect2, varscan2
- PHF19 | c.327G>A p.P109= | Silent (SNP) | VAF 25/226 reads (11%) | catalogued as rs770119298, COSV56490310; called by muse, mutect2, varscan2
- PLCH1 | c.3312T>C p.G1104= (on ENST00000340059 / NM_001130960.2; = p.G1096= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/227 reads (22%) | catalogued as rs1397861999, COSV58194140; called by muse, mutect2, varscan2
- PPFIBP1 | c.1284T>G p.T428= (on ENST00000318304 / NM_177444.3; = p.T411= on NM_003622.4) | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as rs760404658, COSV99944913; called by muse, mutect2
- PWWP2A | c.1500C>G p.G500= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100193931; called by muse, mutect2, varscan2
- TBX21 | c.690G>A p.A230= | Silent (SNP) | VAF 35/91 reads (38%) | catalogued as rs967623871, COSV51597260; called by muse, mutect2, varscan2
- TJP1 | c.3135C>T p.Y1045= | Silent (SNP) | VAF 83/274 reads (30%) | catalogued as rs373853690; called by muse, mutect2, varscan2
- TUBD1 | c.468G>A p.Q156= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as COSV100360122; called by muse, mutect2, varscan2
- UGT2B15 | c.1353T>C p.H451= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as rs769859658, COSV100592342; called by muse, mutect2, varscan2
- WDFY3 | c.585G>A p.V195= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV99883891; called by muse, mutect2, varscan2
- ZNF202 | c.999G>C p.L333= | Silent (SNP) | VAF 9/266 reads (3%) | catalogued as COSV100279065; called by muse, mutect2
- ZSCAN2 | c.714C>T p.I238= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV100306906, COSV57572154; called by muse, mutect2, varscan2
- TSPAN14 | chr10:80520682 G>A | 3'Flank (SNP) | VAF 133/408 reads (33%) | catalogued as COSV99627868; called by muse, mutect2, varscan2
